Somatic mutation profile of tumor specimen C3L-01633-02 (aliquot CPT0091910009) from CPTAC case C3L-01633, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 60.6 years (22,150 days).
Specimen C3L-01633-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f95fe22-2cf1-447d-9812-ca5a3cdc323a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01633-31 (Blood Derived Normal), aliquot CPT0093690002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a98adb97-ea95-46e4-af36-60da257dec84

The open-access MAF lists 87 somatic variants for this specimen: 65 protein-altering or splice-affecting, 15 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 15, Frame Shift Del 6, Nonsense Mutation 3, Intron 3, Splice Site 2, 3'UTR 2, RNA 1, Frame Shift Ins 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.3826C>T p.R1276* | Nonsense Mutation (SNP) | VAF 27/107 reads (25%) | hotspot (GDC flag); catalogued as COSV61370466; called by muse, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 74/371 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 162/630 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs398123322, COSV64289089, COSV64294277; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.802-51_802-1del p.X268_splice | Splice Site (DEL) | VAF 26/178 reads (15%) | hotspot (GDC flag); called by mutect2, pindel
- ABCA2 | c.1789G>A p.G597S (on ENST00000614293; = p.G567S on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.044); catalogued as rs768403966, COSV99686822; called by muse, mutect2, varscan2
- ALKBH8 | c.1111G>C p.E371Q | Missense Mutation (SNP) | VAF 72/379 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1467716924; called by muse, mutect2, varscan2
- ATP8A2 | c.2563G>A p.A855T | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200573494, COSV54938064; called by mutect2, varscan2
- BRWD3 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 66/331 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100956362; called by muse, mutect2, varscan2
- CASP8 | c.1228_1229del p.V410Ffs*28 (on ENST00000432109 / NM_033355.3; = p.V427Ffs*28 on NM_001228.4) | Frame Shift Del (DEL) | VAF 28/278 reads (10%) | catalogued as rs587776665; called by pindel, varscan2
- CIC | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 43/341 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1022815399; called by muse, mutect2, varscan2
- CLPSL1 | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 41/241 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.255); catalogued as rs774480808; called by muse, mutect2, varscan2
- CNTN4 | c.2017C>T p.R673C | Missense Mutation (SNP) | VAF 101/499 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs530287934, COSV61872950; called by muse, mutect2, varscan2
- COPG1 | c.2534G>A p.R845Q | Missense Mutation (SNP) | VAF 56/287 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as rs763080581; called by muse, mutect2, varscan2
- DCAF8L2 | c.1219G>A p.V407M | Missense Mutation (SNP) | VAF 22/346 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV101445775; called by muse, mutect2
- EXOC7 | c.74T>A p.L25Q | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV58741564; called by muse, mutect2, varscan2
- FRMPD3 | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs750463805, COSV52188915; called by muse, mutect2, varscan2
- FYCO1 | c.4324G>A p.G1442S | Missense Mutation (SNP) | VAF 67/596 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144587102; called by muse, mutect2, varscan2
- GPR141 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.829); catalogued as rs375407880; called by muse, varscan2
- HIVEP3 | c.2608G>A p.E870K | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as rs1458595572; called by muse, mutect2, varscan2
- KIF21B | c.2591G>A p.R864H | Missense Mutation (SNP) | VAF 58/429 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as rs201161747, COSV100144655, COSV100144901; called by muse, mutect2, varscan2
- KLK12 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 55/454 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs777184648; called by muse, mutect2, varscan2
- MAP3K1 | c.3989del p.S1330Wfs*6 | Frame Shift Del (DEL) | VAF 30/304 reads (10%) | catalogued as COSV68121509, COSV68122713; called by mutect2, pindel, varscan2
- MAP3K4 | c.3769C>T p.R1257* | Nonsense Mutation (SNP) | VAF 18/157 reads (11%) | catalogued as COSV100815081; called by muse, mutect2, varscan2
- NRXN3 | c.2420G>A p.R807H (on ENST00000335750 / NM_001330195.2; = p.R434H on NM_004796.6) | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV59758617; called by muse, mutect2, varscan2
- NT5C1B | c.517G>A p.G173R (on ENST00000359846 / NM_001199086.2; = p.G113R on NM_033253.4) | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as rs1426309046; called by muse, mutect2, varscan2
- OR10A3 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs375829095, COSV62459852; called by muse, mutect2, varscan2
- OR10Q1 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 54/265 reads (20%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.602); catalogued as rs757666569, COSV57470893; called by muse, mutect2, varscan2
- PCDHA5 | c.272G>T p.R91L | Missense Mutation (SNP) | VAF 93/519 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.988); catalogued as COSV65354060; called by muse, mutect2, varscan2
- PRH2 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.326); catalogued as rs374107851; called by muse, mutect2, varscan2
- PTPRT | c.3568C>T p.R1190W | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs370873414, COSV61972527; called by muse, mutect2, varscan2
- RING1 | c.238G>T p.G80W | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1232970688, COSV63002225, COSV63002625; called by muse, mutect2, varscan2
- SERHL2 | c.334G>A p.V112I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs1437848745; called by mutect2, varscan2
- SIX2 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.089); catalogued as rs373961258; called by muse, mutect2, varscan2
- SYCP2L | c.1440C>T p.H480= | Splice Region (SNP) | VAF 22/105 reads (21%) | catalogued as rs372275947; called by muse, mutect2, varscan2
- TBC1D16 | c.961G>A p.G321S | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201374178; called by muse, mutect2, varscan2
- TMEM67 | c.2107G>T p.G703* | Nonsense Mutation (SNP) | VAF 56/310 reads (18%) | catalogued as COSV60038646; called by muse, mutect2, varscan2
- TNFRSF25 | c.1058C>T p.T353M | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.82); catalogued as COSV61068431; called by muse, mutect2, varscan2
- TPO | c.1402G>A p.G468S | Missense Mutation (SNP) | VAF 93/409 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV100221475, COSV100221758; called by muse, mutect2, varscan2
- VWA5B1 | c.1048T>G p.S350A | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.093); catalogued as rs1369112755; called by muse, mutect2, varscan2
- ARHGAP35 | c.4165A>G p.N1389D | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ARL14EP | c.320G>A p.R107K | Missense Mutation (SNP) | VAF 38/266 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- CTCF | c.626del p.K209Rfs*13 | Frame Shift Del (DEL) | VAF 112/595 reads (19%) | called by mutect2, pindel, varscan2
- DDX43 | c.1471A>C p.I491L | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- DNPH1 | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DSG3 | c.421C>A p.L141I | Missense Mutation (SNP) | VAF 46/259 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- FAM135A | c.3158A>G p.D1053G (on ENST00000370479 / NM_001351599.1; = p.D840G on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/258 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FDPS | c.301C>T p.H101Y | Missense Mutation (SNP) | VAF 55/255 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- HMX1 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- MAGEE1 | c.1250G>T p.S417I | Missense Mutation (SNP) | VAF 25/277 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.189); called by muse, mutect2
- MAOA | c.798C>G p.C266W | Missense Mutation (SNP) | VAF 50/419 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MED13L | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 104/465 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MEPCE | c.536_537del p.S179Cfs*14 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | called by pindel, varscan2
- MON1A | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- N4BP2L2 | c.364G>C p.A122P | Missense Mutation (SNP) | VAF 51/257 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- NAA15 | c.1629del p.K543Nfs*2 | Frame Shift Del (DEL) | VAF 40/237 reads (17%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1650_1651insC p.K551Qfs*5 (on ENST00000521381 / NM_181523.3; = p.K281Qfs*5 on NM_181504.4) | Frame Shift Ins (INS) | VAF 45/262 reads (17%) | called by mutect2, pindel, varscan2
- PPP4C | c.175T>A p.F59I | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- RET | c.2077C>T p.R693C | Missense Mutation (SNP) | VAF 61/241 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SGSM1 | c.19+2dup p.X7_splice | Splice Site (INS) | VAF 17/88 reads (19%) | called by mutect2, pindel, varscan2
- SLC39A7 | c.496del p.R166Afs*72 | Frame Shift Del (DEL) | VAF 52/356 reads (15%) | called by mutect2, pindel, varscan2
- SLX4 | c.4783C>A p.L1595M | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ST6GAL1 | c.116A>C p.K39T | Missense Mutation (SNP) | VAF 62/358 reads (17%) | PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TNS3 | c.1612G>T p.V538F | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- TSC1 | c.1609C>T p.H537Y | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- YTHDF2 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 48/207 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ACAN | c.972C>T p.G324= | Silent (SNP) | VAF 18/113 reads (16%) | catalogued as rs776059900, COSV61363327, COSV61366155; called by muse, mutect2, varscan2
- B4GALT2 | c.48G>A p.V16= | Silent (SNP) | VAF 41/249 reads (16%) | catalogued as rs1485777034, COSV52545539; called by muse, mutect2, varscan2
- CBLN2 | c.159C>T p.N53= | Silent (SNP) | VAF 36/159 reads (23%) | catalogued as COSV54052649; called by muse, mutect2, varscan2
- HEATR3 | c.1617G>A p.Q539= | Silent (SNP) | VAF 53/207 reads (26%) | catalogued as COSV99589754; called by mutect2, varscan2
- HNF1A | c.42G>C p.A14= | Silent (SNP) | VAF 71/377 reads (19%) | catalogued as CX133611; called by muse, mutect2, varscan2
- KNDC1 | c.2469C>T p.H823= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as rs560440547; called by muse, mutect2, varscan2
- MEST | c.63C>T p.A21= | Silent (SNP) | VAF 31/115 reads (27%) | catalogued as rs782057178, COSV56227982; called by muse, mutect2, varscan2
- OPTN | c.1584T>C p.S528= | Silent (SNP) | VAF 88/513 reads (17%) | called by muse, mutect2, varscan2
- PGPEP1 | c.309C>T p.P103= | Silent (SNP) | VAF 57/373 reads (15%) | catalogued as rs761978109; called by muse, mutect2, varscan2
- PLCB3 | c.780C>T p.N260= | Silent (SNP) | VAF 63/268 reads (24%) | called by muse, mutect2, varscan2
- POU6F2 | c.1902G>A p.G634= | Silent (SNP) | VAF 133/618 reads (22%) | called by muse, mutect2, varscan2
- SH3TC1 | c.2730G>A p.G910= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as rs1400205444, COSV99795228; called by muse, mutect2, varscan2
- SLC36A2 | c.942G>A p.A314= | Silent (SNP) | VAF 48/366 reads (13%) | catalogued as rs762445214, COSV58865168; called by muse, mutect2, varscan2
- TFAP2D | c.357G>A p.A119= | Silent (SNP) | VAF 36/320 reads (11%) | called by muse, mutect2, varscan2
- THNSL2 | c.273T>C p.H91= | Silent (SNP) | VAF 34/186 reads (18%) | called by muse, mutect2, varscan2
- CCDC60 | c.170+4700G>C | Intron (SNP) | VAF 69/353 reads (20%) | catalogued as rs560952745; called by muse, mutect2, varscan2
- FNIP2 | c.655+39T>A | Intron (SNP) | VAF 34/186 reads (18%) | called by muse, mutect2, varscan2
- HPS4 | c.*841C>T | 3'UTR (SNP) | VAF 46/165 reads (28%) | catalogued as rs575920373; called by muse, mutect2, varscan2
- LY6K | c.-132C>T | 5'UTR (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- P4HB | c.*2A>G | 3'UTR (SNP) | VAF 41/245 reads (17%) | called by muse, mutect2, varscan2
- SDHAP1 | n.1451G>A | RNA (SNP) | VAF 40/482 reads (8%) | catalogued as rs772517221; called by muse, mutect2
- WARS1 | c.99+3052G>C | Intron (SNP) | VAF 18/234 reads (8%) | called by muse, mutect2
